Somatic mutation profile of tumor specimen MP2PRT-PAVPXM-TMP1-A (aliquot MP2PRT-PAVPXM-TMP1-A-1-0-D-A81A-36) from MP2PRT case MP2PRT-PAVPXM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.6 years (581 days).
Specimen MP2PRT-PAVPXM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9f082d91-1fb3-405e-9a51-474c197ec56c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVPXM-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVPXM-NB1-A-1-0-D-A81A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fc3b44d6-ee31-4f07-bf51-441e55c95043

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NUAK1 | c.1891C>T p.R631W | Missense Mutation (SNP) | VAF 184/403 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); catalogued as rs552453023, COSV99776792; called by muse, mutect2, varscan2
- PNPLA1 | c.898C>T p.R300W (on ENST00000394571 / NM_001374623.1; = p.R205W on NM_173676.2) | Missense Mutation (SNP) | VAF 146/503 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as rs754166062, COSV57233017; called by muse, mutect2, varscan2
- PRB2 | c.494A>G p.Q165R | Missense Mutation (SNP) | VAF 319/772 reads (41%) | SIFT tolerated (0.67); PolyPhen benign (0.01); catalogued as rs1179804194, COSV66983643; called by muse, varscan2
